CCDI case PBBVAT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/49ced1bc-ce76-43d6-aaff-7bbfa44231f9

Demographics
Sex at birth: female; Race: american indian or alaska native; Vital status: Alive.

Diagnoses (1)
1. Myxofibrosarcoma: ICD-O-3 morphology code: 8811/3; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 6.0 years (2,204 days).

Biospecimens (4 samples)
- Sample 0DIQZM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DIR06, 0DIR2J (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIW79: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
